Surgical pathology report (de-identified scan), TCGA case TCGA-61-2016, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2016-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY –

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING OVARY AND FALLOPIAN TUBE (see comment).
- B. LYMPHOVASCULAR SPACE INVASION IDENTIFIED.

PART 2: UTERUS, CERVIX AND LEFT ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND LEFT SALPINGO-OOPHORECTOMY (72 grams) –

- A. HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING LEFT OVARY AND FALLOPIAN TUBE, AND UTERINE SEROSA (SEE COMMENT).
- B. ATROPHIC ENDOMETRIUM.
- C. UNREMARKABLE MYOMETRIUM.
- D. CHRONIC CERVICITIS.

PART 3: OMENTUM, OMENTECTOMY –

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 4: LESION, RIGHT SIDEWALL, BIOPSY –

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 5: APPENDIX, APPENDECTOMY –

APPENDIX WITH OBLITERATION OF DISTAL LUMEN.

PART 6: "CUL-DE-SAC TUMOR", EXCISION –

HIGH-GRADE PAPILLARY SEROUS CARCINOMA INVOLVING FIBROUS TISSUE.

MICROSCOPIC:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 4 cm
TUMOR TYPE:	Papillary serous carcinoma

HISTOLOGIC SILVERBERG GRADE:

ARCHITECTURAL PATTERN:

CYTOLOGIC ATYPIA:

MITOTIC COUNTS / 10hpf:

VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file f8597afc-030e-4c7a-b1bb-c0590827685c (TCGA-61-2016.1BB87FDE-9FF0-4C33-A388-B655F9647407.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).